Gene-level copy-number profile of tumor specimen TCGA-EA-A5O9-01A from TCGA case TCGA-EA-A5O9, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Exocervix; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 39.6 years (14,472 days).
Specimen TCGA-EA-A5O9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.511a7211-0cdd-4d64-8093-57413ad6c015.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EA-A5O9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a75b09f3-4906-4861-8f06-b83b8300ba4d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,150; copy number 2: 29,791; copy number 3: 22,493; copy number 4: 4,404; copy number 5: 666; copy number 6: 210; copy number 7: 769; copy number 9: 54; copy number 11: 68; copy number 12: 106; copy number 14: 2; copy number 15: 99.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EA-A5O9-01A-11D-A28A-01): tumor purity 0.85, ploidy 2.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,974 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:147,939,905–198,222,513, 906 genes, copy number 6–7 (broad region; genes not listed).
- chr5:51,886,688–55,840,025, 72 genes, copy number 6–9 (broad region; genes not listed).
- chr8:40,530,590–40,901,854, 2 genes, copy number 5 (within-gene range 2–5): ZMAT4, AC048387.1.
- chr8:142,657,460–145,066,685, 157 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:99,020,949–100,358,885, 1 gene, copy number 6 (within-gene range 2–6): CNTN5.
- chr11:100,336,856–106,132,116, 96 genes, copy number 6–11 (broad region; genes not listed).
- chr12:40,140,926–40,570,832, 8 genes, copy number 9: LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P.
- chr12:40,728,811–40,729,897, 1 gene, copy number 9: AC016144.1.
- chr12:54,121,277–54,189,008, 1 gene, copy number 5 (within-gene range 4–5): SMUG1.
- chr12:54,145,069–73,208,317, 488 genes, copy number 5–15 (broad region; genes not listed).
- chr16:8,276,263–11,926,307, 106 genes, copy number 12 (within-gene range 2–12) (broad region; genes not listed).
- chr21:10,328,411–19,621,545, 136 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,150. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
